Surgical pathology report (de-identified scan), TCGA case TCGA-IB-AAUW, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-AAUW-01A (Primary Tumor).

[page 1 of 4]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected		Time Received	
Time Reported		Time Transmitted	
Order Number		Ordering Provider	
Status	Final	Relevant Information	
Copied To		Location	ICD O-3
Report Patient	Nam		Adenocarcinoma duct NOS 8500/3
Demographics (for verification purposes)			Site: Pancreas head C25.0
	Sex: F		Q2 5/20/14

ADDENDUM REPORT

*****Addendum Report*****

Accession Number

Collected Date/Time

Received Date/Time

Pathologist

Addendum Reason

Grade listed in the diagnostic line was incorrectly listed as moderately instead of poorly in the original report.

Addendum Diagnosis

PLEASE NOTE: This Addendum Report introduces a potentially significant change in the diagnosis or a change in patient information. Please clearly mark the Original Report as having been changed, with a clear reference to this Addendum Report (e.g. "Please see additional report").

Diagnosis

A. Lymph Node, Group B, Resection:

- Two lymph nodes, negative for malignancy (0/2)

B. Gallbladder, Cholecystectomy:

- Acute cholecystitis
- Cholelithiasis

C. Lymph Node, Peripancreatic, Resection:

- Fibrofatty tissue, negative for malignancy
- Lymphoid tissue not identified

D. Pancreatico-duodenectomy, Whipple Resection:

- Invasive pancreatic ductal adenocarcinoma, poorly differentiated, size, 3.5 x 2.1 cm (see synoptic report)
- Adenocarcinoma within 0.2 cm from the vascular bed and 0.1 cm from the uncinate resection margin
- Bile duct resection margin and pancreatic body resection margin, negative for malignancy
- Six lymph nodes, negative for malignancy (0/6)

E. Lymph Node, Portal, Resection:

- One lymph node, positive for metastatic carcinoma (1/1)
- Size of metastatic deposit, 0.5 cm
- Extracapsular invasion identified

Reported by:

Electronically signed by:

Verified:

Responsible Resident:

Addendum Discussion

The grade was correctly listed as poorly differentiated in the synoptic line but incorrectly listed as moderately differentiated in the diagnosis line in the original report.

*****Surgical Pathology Report*****

Accession Number

[page 2 of 4]
Collected Date/Time
Received Date/Time
Pathologist
Specimen Description
A. Lymph node group 8 at
B. Gallbladder at
C. Prepancreatic lymph node at
D. Whipple specimen at
E. Portal lymph node at
Clinical Information
Mass in head of pancreas.

Diagnosis

- A. Lymph Node, Group B, Resection:
- Two lymph nodes, negative for malignancy (0/2)
- B. Gallbladder, Cholecystectomy:
- Acute cholecystitis
- Cholelithiasis
- C. Lymph Node, Peripancreatic, Resection:
- Fibrofatty tissue, negative for malignancy
- Lymphoid tissue not identified
- D. Pancreatico-duodenectomy, Whipple Resection:
- Invasive pancreatic ductal adenocarcinoma, moderately differentiated, size, 3.5 x 2.1 cm (see synoptic report)
- Adenocarcinoma within 0.2 cm from the vascular bed and 0.1 cm from the uncinate resection margin
- Bile duct resection margin and pancreatic body resection margin, negative for malignancy
- Six lymph nodes, negative for malignancy (0/6)
- E. Lymph Node, Portal, Resection:
- One lymph node, positive for metastatic carcinoma (1/1)
- Size of metastatic deposit, 0.5 cm
- Extracapsular invasion identified

Reported by:

Electronically signed by:

Verified:

Responsible Resident:

Synoptic Report

SPECIMEN:

Head of pancreas

Body of pancreas

Duodenum

Common bile duct

Gallbladder

PROCEDURE:

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

Pancreatic body

TUMOR SIZE:

Greatest dimension: 3.5 cm

Additional dimensions: 2.1 x 1.8 cm

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G3: Poorly differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades duodenal wall

Tumor invades retroperitoneal soft tissue

MARGINS:

Margins uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 1.0 mm

Specified margin: uncinate

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

No prior treatment

LYMPH-VASCULAR INVASION:

Present

PERINEURAL INVASION:

Present

[page 3 of 4]
PRIMARY TUMOR (pT):

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

Number examined: 9

Number involved: 1

DISTANT METASTASIS (pM):

Not applicable

ADDITIONAL PATHOLOGIC FINDINGS:

Pancreatic intraepithelial neoplasia (highest grade: PanIN III)

CLINICAL HISTORY:

Not specified

Gross Description

Received are specimen containers A to E. All requisitions and specimen containers are labelled with the patient's name, . . . The cassettes and identifiers are labelled with the Surgical Number . . .

A. The specimen is received fresh and is subsequently placed into formalin, designated as "A - lymph node group 8 at . . .". The specimen consists of an irregular portion of fibrofatty tissue measuring 2.0 x 1.4 x 0.5 cm. Two possible lymph nodes are identified ranging in size from 1.2 x 0.8 x 0.3 cm to 1.4 x 0.7 x 0.3 cm. Sections are submitted as follows:

A1. two possible lymph nodes

A2. remainder of tissue submitted in toto

B. The specimen is received fresh and is subsequently placed into formalin, designated as "B - gallbladder at . . .". The specimen consists of a brown tan non-intact gallbladder measuring 11.5 x 4.8 x 2.3 cm. The serosal surface is tan to dark brown, smooth and congested. A surgical defect is identified at the fundus measuring 2.4 cm in length. Cystic duct is patent. Cystic duct lymph node is not identified. The lumen does not contain bile or calculi, however, two calculi are received with the specimen. Both are black and ovoid. The smaller calculus measures 1.0 x 0.7 x 0.5 cm. The larger calculus measures 4.0 x 2.8 x 2.4 cm. There are tan and hemorrhagic exudate adherent to the mucosa. The mucosa is brown and fibrotic. The wall is thickened and averages 0.6 cm in thickness. Sections are submitted as follows:

B1. cystic duct margin and representative sections from neck and body

B2. representative sections from fundus including surgical defect

C. The specimen is received fresh and is subsequently placed into formalin, designated as "C - prepancreatic lymph node at . . .". The specimen consists of a rubbery irregular portion of fibrofatty tissue measuring 2.5 x 1.0 x 0.3 cm. Specimen is submitted in toto in one cassette.

D. The specimen is received fresh and is subsequently placed into formalin, designated as "D - Whipple specimen at . . .". The specimen consists of a whipple's resection including a portion of pancreas (7.0 x 4.0 x 1.5 cm), duodenum (25.0 cm in length and averaging 6.0 cm in circumference), and attached peripancreatic soft tissue extending to a maximum depth of 2.5 cm, as well as a small portion of attached mesentery extending to a maximum depth of 2.0 cm. Proximal and distal margins are stapled. Specimen is inked as follows: Body margin orange, vessel bed margin green, uncinate margin blue. The common bile duct measures 4.0 cm in length and averages 0.7 cm in circumference. The body margin of the pancreas measures 2.5 x 1.0 cm. The uncinate margin measures 6.0 x 2.5 cm. The pancreas is serially sectioned. A firm ill-defined yellow to light tan variegated lesion is identified surrounding the common bile duct measuring 3.5 x 2.1 x 1.8 cm. It is 0.5 cm from the common bile duct margin, 1.0 cm to the body margin, 0.1 cm to the vessel bed, 1.2 cm to the uncinate margin, 0.3 cm to the posterior surface, 2.5 cm to the anterior surface, 1.5 cm to the proximal margin, and 18.5 cm to the distal margin. The serosal surface of the duodenum is tan and smooth and appears grossly unremarkable. The mucosa is tan to brown and appears grossly unremarkable. Sections are submitted as follows:

D1. common bile duct margin en face

D2-4. distal margin trisected

D5. proximal margin bisected

D6. shaved section body margin including pancreatic duct margin

D7-8. contiguous section bisected, demonstrating lesion in closest relation to the vessel bed

margin also including uncinate margin

D9-10. contiguous section bisected, lesion in closest relation to uncinate margin and posterior

surface which is inked purple

D11-12. contiguous section bisected, lesion underlying duodenal mucosa and including vessel bed margin

D13. lesion in relation to anterior surface

D14. lesion in relation to posterior surface

[page 4 of 4]
- D15. grossly uninvolved pancreas including vessel bed margin
D16. transition from common bile duct through ampulla of Vater
D17. four possible peripancreatic lymph nodes ranging in size from 0.5 x 0.4 x 0.3 cm to 1.3 x 0.8 x 0.3 cm

E. The specimen is received fresh and is subsequently placed into formalin, designated as "E - portal lymph node". The specimen consists of an irregular portion of fibrofatty tissue measuring 2.8 x 1.8 x 0.8 cm. A possible lymph node is identified measuring 2.3 x 1.4 x 0.8 cm. Possible lymph node is bisected and submitted in toto in cassettes E1 and E2.

Sample and Test Request Deficiency

Minor sample and/or test request deficiency.

Location of physician not provided.

Pathologist Comment

representative tumour block=D10

Normal block=D15

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file 3974ab5d-6576-4a73-9058-041d2b5fb06b (TCGA-IB-AAUW.64606B7A-008D-459F-8E32-296016364BB1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).